Somatic mutation profile of tumor specimen TCGA-AX-A1C5-01A (aliquot TCGA-AX-A1C5-01A-11D-A135-09) from TCGA case TCGA-AX-A1C5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 47.6 years (17,383 days).
Specimen TCGA-AX-A1C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 783c24f4-39c9-4d4b-a59a-6d179d6103b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1C5-10A (Blood Derived Normal), aliquot TCGA-AX-A1C5-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a1f2606-be58-43ce-aedb-ee533298c02e

The open-access MAF lists 1,037 somatic variants for this specimen: 725 protein-altering or splice-affecting, 281 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 599, Silent 281, Frame Shift Del 60, Nonsense Mutation 39, Intron 14, Splice Region 9, Frame Shift Ins 8, RNA 7, Splice Site 6, 5'Flank 5, In Frame Del 3, 3'UTR 3.

Variants (750 of 1,037; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123105, CM950052, CM960042, COSV99497942; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912679, CM080031, COSV55117476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTCF | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV50488736; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- PCGF2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1567941256; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs779070661, CM1414538, COSV59954404; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 29/98 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3637C>T p.R1213* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as rs587777169, CM133263, COSV100741495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TTN | c.53947C>T p.R17983* (on ENST00000591111; = p.R10559* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as rs1553649171, COSV60435736; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel, varscan2
- AASDH | c.2306C>A p.A769D | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221959; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA7 | c.2969C>T p.T990M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143226982, COSV54033206; called by muse, mutect2, varscan2
- ABCB6 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.13); catalogued as COSV99522336; called by muse, mutect2
- ABCC12 | c.2717G>A p.G906D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253345; called by muse, mutect2, varscan2
- ABCG5 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV99575680; called by muse, mutect2, varscan2
- ABL1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584735, COSV59329201; called by muse, mutect2, varscan2
- AC008676.3 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV100400524; called by muse, mutect2, varscan2
- AC008676.3 | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100400525; called by muse, varscan2
- AC008676.3 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV100400526, COSV56635741; called by muse, varscan2
- ACD | c.1622C>T p.P541L (on ENST00000620338; = p.P452L on NM_022914.3) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99538024; called by muse, mutect2, varscan2
- ACOT7 | c.1022C>T p.S341L (on ENST00000377855 / NM_181864.3; = p.S331L on NM_007274.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1168586569, COSV100830328; called by muse, mutect2, varscan2
- ACVR1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs201452185; ClinVar: benign; called by muse, mutect2, varscan2
- ADAMTS14 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767274241, COSV100941525; called by muse, mutect2, varscan2
- ADAMTS14 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528519283, COSV64599875; called by muse, mutect2, varscan2
- ADGRG1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs778915635, COSV101113582; called by muse, mutect2, varscan2
- ADGRG6 | c.2249A>G p.N750S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as COSV99748966; called by muse, mutect2, varscan2
- AFF2 | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781941308, COSV53983566; called by muse, mutect2, varscan2
- AFF3 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as rs755648740, COSV100420218; called by muse, mutect2, varscan2
- AGMO | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100694841; called by muse, mutect2, varscan2
- AKNAD1 | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs769460343, COSV100645926; called by muse, mutect2, varscan2
- AMD1 | c.670A>G p.N224D | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV64387813; called by muse, mutect2, varscan2
- ANK2 | c.6170C>T p.P2057L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs146531225; called by muse, mutect2, varscan2
- ANKRD30A | c.3229G>A p.D1077N (on ENST00000611781; = p.D1021N on NM_052997.2) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100654526, COSV64604435; called by muse, mutect2, varscan2
- ANLN | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV99732954; called by muse, mutect2, varscan2
- ANTXR1 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV58015869; called by muse, mutect2, varscan2
- AP1B1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750286015, COSV100434857; called by muse, mutect2, varscan2
- APPL1 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs753618573, COSV55701941; called by muse, mutect2, varscan2
- ARFGEF3 | c.6197G>A p.R2066H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1351780050, COSV99294841; called by muse, mutect2, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARMC5 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs562207027, COSV99192877; called by muse, mutect2, varscan2
- ASAH2 | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764774098, COSV100270188; called by muse, mutect2, varscan2
- ASMT | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV101172557; called by muse, mutect2, varscan2
- ASPRV1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs755538169, COSV100208657; called by muse, varscan2
- ASTN1 | c.2836T>C p.C946R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100707798; called by muse, mutect2, varscan2
- ATG2B | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761750367, COSV99951992; called by muse, mutect2, varscan2
- ATP4B | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100089966; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368301208, COSV100023748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP9A | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100125702, COSV58763316; called by muse, mutect2
- AUH | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.083); catalogued as COSV100342870; called by muse, mutect2, varscan2
- BACH1 | c.1580C>A p.P527Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99728777; called by muse, mutect2
- BACH2 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs767372478, COSV57600059; called by muse, mutect2, varscan2
- BCAS3 | c.2318C>T p.T773M (on ENST00000390652 / NM_001353144.2; = p.T758M on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs759264893, COSV66777260; called by muse, mutect2, varscan2
- BCL6B | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs753410593, COSV53428662; called by muse, mutect2, varscan2
- BRD3 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100325602; called by muse, mutect2, varscan2
- BRSK2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV57544910; called by muse, mutect2
- BSDC1 | c.192G>A p.T64= | Splice Region (SNP) | VAF 13/35 reads (37%) | catalogued as rs540910979, COSV100345168; called by muse, mutect2, varscan2
- BTBD2 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438437676, COSV99724757; called by muse, mutect2, varscan2
- BTN2A1 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100438811; called by muse, mutect2, varscan2
- C20orf194 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs372426469; called by muse, mutect2, varscan2
- C3 | c.3370G>A p.V1124M | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1280952198, COSV99837338; called by muse, mutect2, varscan2
- C3orf20 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99514650; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs372345940; called by mutect2, varscan2
- C9 | c.550del p.D184Ifs*7 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as COSV54682641; called by mutect2, pindel, varscan2
- CA3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770535043, COSV53409913; called by muse, mutect2, varscan2
- CACNA1G | c.2669A>G p.K890R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV100662677; called by muse, mutect2, varscan2
- CACNB2 | c.1937G>A p.R646Q (on ENST00000324631 / NM_201596.3; = p.R591Q on NM_000724.4) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.974); catalogued as rs374454040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB3 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as rs201472603, COSV56397378; called by muse, varscan2
- CADM2 | c.293A>G p.D98G (on ENST00000407528 / NM_001167674.2; = p.D100G on NM_153184.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101059650; called by muse, mutect2, varscan2
- CALCOCO2 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.794); catalogued as rs781069382, COSV99363979; called by muse, mutect2, varscan2
- CAND1 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101598294; called by muse, mutect2, varscan2
- CAPN10 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as COSV99550589; called by muse, mutect2, varscan2
- CATSPERE | c.1937G>T p.C646F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100835398; called by muse, mutect2, varscan2
- CBLB | c.1307G>A p.C436Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV99914512; called by muse, mutect2, varscan2
- CCDC113 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99541261; called by muse, mutect2, varscan2
- CCDC144A | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV61402412, COSV61402991; called by muse, mutect2, varscan2
- CCDC151 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62697796; called by muse, mutect2, varscan2
- CCDC73 | c.2683del p.T895Lfs*8 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs764792181; called by mutect2, pindel, varscan2
- CCHCR1 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs747364417, COSV100885868; called by muse, varscan2
- CCN2 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750532772, COSV100915369; called by muse, varscan2
- CD3D | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs777721098, COSV56140079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD40 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100953877; called by muse, mutect2, varscan2
- CDC23 | c.388_390del p.K130del | In Frame Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs746562443; called by pindel, varscan2
- CDC27 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV50702823; called by muse, mutect2, varscan2
- CDC45 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as rs142384320; called by muse, varscan2
- CDCP1 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs758270201, COSV99944373; called by muse, mutect2, varscan2
- CDH18 | c.1750C>A p.L584I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs372726350, COSV56946784; called by muse, mutect2, varscan2
- CDKL5 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.778); catalogued as rs745508309, CM1514206, COSV66110161; called by muse, mutect2, varscan2
- CDX4 | c.501G>A p.T167= | Splice Region (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100999161; called by muse, mutect2, varscan2
- CELF1 | c.1169C>T p.A390V (on ENST00000358597 / NM_001376422.1; = p.A386V on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as COSV60113685; called by muse, mutect2, varscan2
- CELSR2 | c.2977G>A p.V993I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs988336317, COSV99603307; called by muse, mutect2, varscan2
- CEMIP2 | c.3112G>A p.V1038I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs780192646, COSV65484831; called by muse, mutect2, varscan2
- CEP250 | c.4496G>A p.R1499Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs756362141, COSV61168263; called by muse, mutect2, varscan2
- CEP350 | c.7682A>G p.Q2561R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100855345; called by muse, mutect2, varscan2
- CEP85L | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100821470; called by muse, mutect2
- CES2 | c.816G>A p.T272= | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as rs142953579, COSV100399449; called by muse, varscan2
- CFP | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1223823897, COSV99901707; called by muse, mutect2, varscan2
- CHAF1A | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs770871515, COSV56675620; called by muse, varscan2
- CHD4 | c.1385G>A p.C462Y (on ENST00000357008 / NM_001363606.2; = p.C475Y on NM_001273.5) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100539361; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHERP | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99550188; called by muse, mutect2, varscan2
- CHID1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs376582815; called by muse, mutect2, varscan2
- CHKA | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761582548, COSV99694452; called by muse, mutect2, varscan2
- CHMP2A | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99448397; called by muse, mutect2, varscan2
- CHRM4 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100708743; called by muse, mutect2, varscan2
- CHST2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs975880815, COSV58884969; called by muse, mutect2, varscan2
- CIC | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs1391719010, COSV50560274; called by muse, mutect2, varscan2
- CIT | c.5171T>C p.I1724T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99951137; called by muse, varscan2
- CIT | c.3868C>T p.R1290W | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99951143; called by muse, mutect2, varscan2
- CLCN6 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1372468629, COSV100411682, COSV100412197; called by muse, mutect2, varscan2
- CLDN1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.279); catalogued as rs772600198, COSV55043353; called by muse, mutect2, varscan2
- CLEC2L | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV70691029; called by muse, mutect2, varscan2
- CLEC7A | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); catalogued as rs373489756; called by muse, mutect2, varscan2
- CLN5 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV101080440; called by muse, mutect2, varscan2
- CMAS | c.1094G>A p.W365* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99982746; called by muse, mutect2, varscan2
- CNGB1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs1316617634, COSV99212232; called by muse, mutect2, varscan2
- CNTN1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.564); catalogued as rs755978506, COSV100751856; called by muse, mutect2, varscan2
- CNTN6 | c.3041T>C p.I1014T | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759673553, COSV100611925; called by muse, mutect2, varscan2
- COL4A1 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs778390847, COSV101011624, COSV65424603; called by muse, mutect2, varscan2
- COL4A3 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs761355107, COSV101170578; called by muse, mutect2, varscan2
- COL5A1 | c.2744C>T p.T915M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771090557, COSV65664976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPG1 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363716962, COSV59114302; called by muse, mutect2, varscan2
- CPNE1 | c.656G>A p.G219E (on ENST00000352393; = p.G224E on NM_003915.5) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100468202; called by muse, mutect2, varscan2
- CPSF7 | c.235A>G p.N79D (on ENST00000394888 / NM_001136040.4; = p.N122D on NM_024811.4) | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.432); catalogued as COSV100467668; called by muse, varscan2
- CPZ | c.922G>A p.G308R (on ENST00000360986 / NM_001014447.3; = p.G297R on NM_003652.3) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV59927065; called by muse, mutect2, varscan2
- CRACDL | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs767437682, COSV67407180; called by muse, mutect2, varscan2
- CRAT | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100540168; called by muse, mutect2, varscan2
- CREBBP | c.2632A>C p.T878P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.543); catalogued as COSV99272406; called by muse, mutect2, varscan2
- CRX | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as rs761290111, COSV55759348, COSV99704366; called by muse, varscan2
- CSPG4 | c.5620C>T p.R1874W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs765136744, COSV100414226; called by muse, varscan2
- CTNNA2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766045574, COSV63560688; called by muse, varscan2
- CTNNB1 | c.1156A>G p.R386G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778731804, COSV100846534; called by muse, mutect2, varscan2
- CTNNBIP1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101032890; called by muse, mutect2, varscan2
- CTSK | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV99649013; called by muse, mutect2, varscan2
- CUL3 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.835); catalogued as COSV52370515; called by muse, mutect2, varscan2
- CYB561 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100669205; called by muse, mutect2, varscan2
- CYGB | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs779650045, COSV99506281; called by muse, mutect2, varscan2
- CYP2D6 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); catalogued as rs77578877, COSV100637225; called by muse, mutect2
- CYP2S1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752402676, COSV59505726; called by muse, varscan2
- CYP4F11 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs771046979, COSV56128516; called by muse, mutect2, varscan2
- DCAF8 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV100470916; called by muse, mutect2, varscan2
- DCHS1 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV100202662; called by muse, mutect2
- DCST1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs144640417; called by muse, varscan2
- DCTN1 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1406215076, COSV62621314; called by muse, mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 4/21 reads (19%) | catalogued as rs755280697; called by mutect2, pindel
- DDX60 | c.2434G>A p.V812M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1441110573, COSV67097499; called by muse, mutect2, varscan2
- DEF8 | c.347G>A p.R116H (on ENST00000268676 / NM_207514.3; = p.R55H on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs372120789; called by muse, mutect2, varscan2
- DENND2B | c.3181C>T p.R1061C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs773519203, COSV100567910; called by muse, mutect2, varscan2
- DENND4A | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298457822, COSV71265355; called by mutect2, varscan2
- DGKA | c.1651A>G p.R551G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100093509; called by muse, mutect2, varscan2
- DGKD | c.1045G>A p.A349T (on ENST00000264057 / NM_152879.3; = p.A305T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs758053252, COSV51126034; called by muse, mutect2, varscan2
- DHX29 | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287766; called by muse, mutect2, varscan2
- DHX38 | c.3490C>T p.R1164W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs527587650, COSV51697696; called by muse, mutect2, varscan2
- DIAPH2 | c.1025A>G p.E342G | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100235600; called by muse, mutect2, varscan2
- DICER1 | c.2723G>A p.G908D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); catalogued as COSV100602611, COSV100602656; called by muse, mutect2, varscan2
- DIP2C | c.3200C>T p.T1067M | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1349744412, COSV99793925; called by muse, mutect2, varscan2
- DIP2C | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1037243274, COSV99793927; called by muse, mutect2, varscan2
- DLGAP4 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs748450222, COSV59419375; called by muse, mutect2, varscan2
- DLST | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1331012371, COSV99472182; called by muse, mutect2, varscan2
- DMTF1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.8); catalogued as rs770114803, COSV100487535; called by muse, mutect2, varscan2
- DNAH10 | c.13295G>A p.R4432Q (on ENST00000409039; = p.R4371Q on NM_207437.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs778688644, COSV99435951; called by muse, mutect2, varscan2
- DNAH5 | c.13463C>T p.P4488L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99454854; called by muse, mutect2, varscan2
- DNAI2 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs766644122, COSV100210147; called by muse, mutect2, varscan2
- DNAJA1 | c.794A>G p.Q265R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs772400138, COSV100438652; called by muse, mutect2, varscan2
- DNAJC18 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV100122217; called by muse, mutect2, varscan2
- DNMT3A | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV53039065, COSV53047637; called by muse, mutect2, varscan2
- DNMT3B | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs576798456, COSV99144809; called by muse, mutect2, varscan2
- DOCK1 | c.4100G>T p.R1367L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as COSV54732875, COSV99733128; called by muse, mutect2, varscan2
- DOCK5 | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770231252, COSV99378127; called by muse, mutect2, varscan2
- DOHH | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171089; called by muse, mutect2, varscan2
- DPP3 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV100855764; called by muse, varscan2
- DPP4 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859130; called by muse, mutect2, varscan2
- DPYD | c.2950G>A p.D984N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs760235888, COSV100929521; called by muse, mutect2, varscan2
- DPYSL5 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.519); catalogued as COSV99982861; called by muse, mutect2, varscan2
- DSG2 | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs764524494, COSV99853302; called by muse, mutect2, varscan2
- DYRK3 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895851; called by muse, mutect2, varscan2
- EDA | c.176G>A p.C59Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV100141028, COSV58877202; called by muse, mutect2, varscan2
- EDC4 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758003306, COSV62765929; called by muse, mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- ELAVL2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1341756308, COSV56371452; called by muse, mutect2, varscan2
- ELK3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs375568901; called by muse, mutect2, varscan2
- ELMO1 | c.1376G>A p.C459Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100166328; called by muse, mutect2, varscan2
- ELMO1 | c.243+1G>A p.X81_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100166331; called by mutect2, varscan2
- ENPP5 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100040676; called by muse, mutect2, varscan2
- EPHB6 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100844467; called by muse, varscan2
- ERO1B | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100524242; called by muse, mutect2, varscan2
- ESR1 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.606); catalogued as rs754403698, COSV99241507; called by muse, varscan2
- ETV6 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs144209028; called by muse, mutect2, varscan2
- EXD1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763820609, COSV59253155; called by muse, mutect2, varscan2
- EYA4 | c.1140G>T p.W380C (on ENST00000531901 / NM_001301013.1; = p.W374C on NM_004100.5) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100766433, COSV62062623; called by muse, mutect2, varscan2
- FAAP100 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs772327939, COSV100585301; called by muse, mutect2, varscan2
- FAHD2B | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as rs757537768, COSV99738316; called by muse, mutect2, varscan2
- FAM110B | c.622A>C p.S208R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as COSV100826290; called by muse, mutect2, varscan2
- FAM193A | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219299, COSV61193813; called by muse, mutect2, varscan2
- FAM47A | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as rs780521265, COSV60495193, COSV60498365, COSV60499348; called by muse, mutect2, varscan2
- FAM47B | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs773159030, COSV61452348; called by muse, mutect2, varscan2
- FANCD2 | c.3620G>A p.G1207D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99812689; called by muse, mutect2, varscan2
- FAT2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs978707253, COSV55833888; called by muse, mutect2, varscan2
- FATE1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs202137219, COSV100948216; called by muse, mutect2, varscan2
- FBXO30 | c.1661G>T p.R554M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99395452; called by muse, mutect2, varscan2
- FBXO7 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs568297516, COSV56678713; called by muse, mutect2, varscan2
- FBXW10 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs755009683, COSV100111158; called by muse, mutect2, varscan2
- FCER2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.053); catalogued as rs149654388, COSV60915920; called by muse, mutect2, varscan2
- FCGBP | c.8956G>A p.A2986T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456141963; called by muse, mutect2, varscan2
- FCGR2B | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99375424; called by muse, mutect2, varscan2
- FCN1 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100878980; called by muse, mutect2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FEZ1 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV54033017; called by muse, mutect2, varscan2
- FFAR2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.313); catalogued as rs775045094, COSV55832218; called by muse, mutect2
- FGD5 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779746404, COSV53248116; called by muse, mutect2, varscan2
- FHDC1 | c.2414A>G p.D805G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99471744; called by muse, mutect2, varscan2
- FHOD1 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs777850281, COSV99263907; called by muse, mutect2, varscan2
- FICD | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766262291, COSV99934493; called by muse, varscan2
- FIGN | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.375); catalogued as rs1327147379, COSV60763922; called by muse, mutect2, varscan2
- FKBP10 | c.1085C>A p.A362D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505356; called by muse, mutect2, varscan2
- FKBP9 | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV99640564; called by muse, mutect2
- FLII | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs754279330, COSV100375724; called by muse, mutect2, varscan2
- FN1 | c.4571G>A p.R1524H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60565144; called by muse, mutect2, varscan2
- FOLR2 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53351035, COSV99995512; called by muse, mutect2, varscan2
- FOXD4 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100071333; called by muse, mutect2, varscan2
- FOXD4L1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1198694016, COSV99380875; called by muse, mutect2, varscan2
- FOXH1 | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100024020; called by muse, varscan2
- FOXK1 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61065680; called by muse, mutect2, varscan2
- FOXR1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs782821168, COSV100393055; called by muse, mutect2, varscan2
- FREM1 | c.5315C>T p.S1772L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs201078694, COSV66525513; called by muse, mutect2, varscan2
- FRMD4A | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100662611; called by muse, mutect2, varscan2
- FSCN3 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs151254172; called by muse, varscan2
- FURIN | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184764; called by muse, mutect2, varscan2
- FXYD4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200599002, COSV72052653; called by muse, mutect2, varscan2
- FZR1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV100553915; called by muse, mutect2, varscan2
- GALP | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.057); catalogued as rs368200734; called by muse, mutect2, varscan2
- GAS7 | c.725G>A p.R242Q (on ENST00000432992 / NM_201433.2; = p.R102Q on NM_003644.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV100097042; called by muse, mutect2, varscan2
- GC | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454524724, COSV56736835; called by muse, mutect2, varscan2
- GCNT1 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.431); catalogued as rs1397099649, COSV100946670; called by muse, mutect2, varscan2
- GGT6 | c.892G>A p.A298T (on ENST00000574154 / NM_001122890.3; = p.A266T on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99627139; called by muse, mutect2
- GHDC | c.1289-1G>T p.X430_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99511633; called by muse, mutect2, varscan2
- GIMAP1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs867001533, COSV56188051; called by muse, mutect2, varscan2
- GLI3 | c.1910A>G p.H637R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV101230081; called by muse, mutect2, varscan2
- GLRA4 | c.1050A>G p.I350M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100129126; called by muse, mutect2, varscan2
- GLYCTK | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as rs781073570, COSV99980971; called by muse, varscan2
- GLYR1 | c.297G>A p.T99= | Splice Region (SNP) | VAF 3/14 reads (21%) | catalogued as rs756278858, COSV58927530; called by muse, mutect2
- GNA12 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980878134, COSV51744718; called by muse, mutect2, varscan2
- GON4L | c.1458G>T p.M486I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV99675921; called by muse, mutect2, varscan2
- GOT1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs772704095, COSV65147316; called by muse, mutect2, varscan2
- GPC3 | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV100893629; called by muse, mutect2, varscan2
- GPC5 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs777139638, COSV100996217, COSV65586209; called by muse, mutect2, varscan2
- GPD2 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100133710; called by muse, mutect2, varscan2
- GPR142 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs374841372, COSV59518684; called by muse, mutect2, varscan2
- GPR158 | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100894361; called by muse, mutect2
- GPR18 | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs549443596, COSV100540677; called by muse, mutect2, varscan2
- GPR78 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs147299352; called by muse, mutect2, varscan2
- GPRC6A | c.1355del p.N452Mfs*2 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs1362947110; called by mutect2, pindel, varscan2
- GPS1 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs754427804, COSV100136159; called by muse, varscan2
- GRID1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201655919, COSV60017942; called by muse, mutect2, varscan2
- GRIN2A | c.3307C>T p.R1103C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs748879665, COSV100411222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIP1 | c.2044C>G p.P682A (on ENST00000359742 / NM_001379345.1; = p.P630A on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs767751370, COSV99669979; called by muse, mutect2, varscan2
- GRM1 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99269381; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs747773579; called by mutect2, varscan2
- GTF2F1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs756437207, COSV101081437; called by muse, varscan2
- GTPBP2 | c.1748G>A p.G583D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100200184; called by muse, mutect2
- H1-1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55119224; called by muse, mutect2, varscan2
- HCAR1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as rs750390654, COSV100811832; called by muse, varscan2
- HCFC2 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV99983322; called by muse, mutect2, varscan2
- HEPACAM2 | c.1046T>C p.L349S (on ENST00000394468 / NM_001039372.4; = p.L337S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100506830; called by muse, mutect2, varscan2
- HERC1 | c.6682C>A p.R2228S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.046); catalogued as COSV101496995; called by muse, mutect2, varscan2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs766204131; called by mutect2, pindel, varscan2
- HGS | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1347251256, COSV61269725; called by muse, mutect2, varscan2
- HGSNAT | c.133del p.R45Dfs*5 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs1220771600; called by mutect2, pindel, varscan2
- HHIPL2 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs777088140, COSV100597141; called by muse, varscan2
- HPS5 | c.2270C>T p.T757I (on ENST00000349215 / NM_181507.2; = p.T643I on NM_007216.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs760229257, COSV100752378; called by muse, mutect2, varscan2
- HSD3B7 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746072197, COSV99288364; called by muse, varscan2
- HSPA1A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.226); catalogued as COSV100989416; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTR5A | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1461352395, COSV55283384, COSV55284497; called by muse, mutect2, varscan2
- HUNK | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213782034, COSV54231687; called by muse, mutect2, varscan2
- HVCN1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs769403674, COSV54373355; called by muse, mutect2, varscan2
- IARS1 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs780409825, COSV65114488; called by muse, mutect2, varscan2
- ICAM2 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56743551; called by muse, mutect2
- IFT81 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs760804753, COSV54362165; called by muse, mutect2, varscan2
- IGF2R | c.5287G>A p.A1763T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs780405127, COSV63626555; called by muse, mutect2, varscan2
- IGSF9 | c.3421C>T p.R1141C (on ENST00000368094 / NM_001135050.2; = p.R1125C on NM_020789.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs750420070, COSV100231387; called by muse, varscan2
- IKBKB | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99059407; called by muse, mutect2, varscan2
- IKBKB | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as CM149161, COSV100645858; called by muse, mutect2, varscan2
- IL16 | c.1832C>A p.P611H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as COSV57264411; called by muse, mutect2, varscan2
- IL1RAPL1 | c.543G>C p.W181C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151054; called by muse, mutect2, varscan2
- ILK | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.242); catalogued as rs1315052873, COSV100196665; called by muse, mutect2, varscan2
- INO80D | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs775445232, COSV68960163; called by muse, mutect2, varscan2
- INPP5D | c.2021G>A p.R674Q (on ENST00000445964 / NM_001017915.3; = p.R673Q on NM_005541.5) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64035697; called by muse, mutect2, varscan2
- INSR | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs773661946, COSV57158436; called by muse, mutect2, varscan2
- IPO9 | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs766333425, COSV64234066; called by muse, mutect2, varscan2
- IQSEC3 | c.2161G>A p.V721M (on ENST00000538872 / NM_001170738.2; = p.V418M on NM_015232.1) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100407684; called by muse, mutect2, varscan2
- ISLR2 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100679811; called by muse, mutect2, varscan2
- ITFG1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1468220255, COSV57745361; called by muse, mutect2, varscan2
- ITFG2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.494); catalogued as COSV99958365; called by muse, mutect2, varscan2
- ITGAM | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as rs777964824, COSV54943880; called by muse, mutect2, varscan2
- ITPR2 | c.6123G>T p.K2041N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101190208; called by muse, mutect2, varscan2
- KANSL3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1479172383, COSV100831257; called by muse, mutect2, varscan2
- KAT6B | c.4789A>G p.S1597G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99769184; called by muse, mutect2
- KCNA3 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901499; called by muse, mutect2, varscan2
- KCNAB2 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs1345584776, COSV99379643; called by muse, mutect2
- KCNH1 | c.2689G>A p.A897T (on ENST00000271751 / NM_172362.3; = p.A870T on NM_002238.4) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99661800; called by muse, mutect2
- KCNH7 | c.2651_2653del p.E884del | In Frame Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs1558923523; called by mutect2, pindel, varscan2
- KCNJ4 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs147603955, COSV57858528, COSV57859077; called by muse, mutect2, varscan2
- KCNT1 | c.895G>A p.G299S (on ENST00000488444; = p.G318S on NM_020822.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99706456, COSV99706836; called by muse, mutect2
- KCNT1 | c.3523G>A p.V1175I (on ENST00000488444; = p.V1180I on NM_020822.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs754383898, COSV99706839; called by muse, varscan2
- KCTD20 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as rs768292697, COSV99536287; called by muse, mutect2, varscan2
- KDM2B | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100997678; called by muse, mutect2
- KDM5B | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs761791060, COSV52510273, COSV99349807; called by muse, mutect2, varscan2
- KIAA1614 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs369718466; called by muse, varscan2
- KIF13B | c.4078C>T p.R1360C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253902563, COSV101576075; called by muse, mutect2, varscan2
- KIF22 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as rs764538488, COSV99361548; called by muse, mutect2, varscan2
- KIF7 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs150543610; called by muse, mutect2, varscan2
- KLF10 | c.4C>T p.L2F | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99574972; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV54711577; called by mutect2, varscan2
- KMT2C | c.14024C>T p.A4675V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.69); catalogued as rs775326119, COSV100077228; called by muse, mutect2, varscan2
- KNTC1 | c.930G>A p.T310= | Splice Region (SNP) | VAF 7/13 reads (54%) | catalogued as rs1219776941, COSV100338854; called by muse, mutect2, varscan2
- KRT26 | c.992T>C p.L331S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100156627; called by muse, mutect2, varscan2
- KRT8 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs997730766, COSV99510341; called by muse, mutect2, varscan2
- KRTAP13-2 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV101299679, COSV67761876; called by muse, mutect2, varscan2
- KRTAP19-8 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101239222; called by muse, mutect2, varscan2
- LAPTM5 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs139678458; called by muse, varscan2
- LCTL | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100427322; called by muse, mutect2, varscan2
- LDLR | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749038326, CM930473, CM970870, COSV99370378; ClinVar: pathogenic / conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- LPCAT4 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100149229; called by muse, mutect2, varscan2
- LPP | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs755218802, COSV100447890; called by muse, mutect2, varscan2
- LRP1 | c.11095C>T p.R3699W | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54520484; called by muse, mutect2, varscan2
- LRP1B | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101261702, COSV67247880; called by muse, mutect2
- LRP8 | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.898); catalogued as COSV100036994; called by muse, mutect2, varscan2
- LRRC4 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975260; called by muse, mutect2
- LRRC8B | c.1215G>T p.W405C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100446723; called by muse, mutect2, varscan2
- LSM1 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277813415, COSV100258506; called by muse, mutect2, varscan2
- LTBP4 | c.3136G>A p.G1046R (on ENST00000308370 / NM_001042544.1; = p.G1009R on NM_003573.2) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); catalogued as rs562454425, COSV52581344; called by muse, mutect2, varscan2
- LTBP4 | c.4649G>A p.R1550H (on ENST00000308370 / NM_001042544.1; = p.R1513H on NM_003573.2) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99199709; called by muse, mutect2, varscan2
- LY75 | c.4717G>A p.V1573I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1291820587, COSV99717116; called by muse, mutect2, varscan2
- LYAR | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs756569454, COSV100603446; called by muse, mutect2, varscan2
- MAGED1 | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100431876; called by muse, mutect2, varscan2
- MAP3K10 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53421236; called by muse, mutect2
- MAP3K5 | c.4043A>G p.D1348G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100753347; called by muse, mutect2, varscan2
- MARK2 | c.2105C>T p.T702M (on ENST00000402010 / NM_001039469.2; = p.T638M on NM_004954.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100036393; called by muse, mutect2, varscan2
- MBNL2 | c.702T>G p.F234L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV100600577; called by muse, mutect2, varscan2
- MCM3 | c.716C>T p.A239V (on ENST00000229854 / NM_001366374.2; = p.A229V on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1478419288, COSV100009123; called by muse, mutect2, varscan2
- MCTP2 | c.2216C>T p.T739I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100752572; called by muse, varscan2
- MDN1 | c.14305G>A p.E4769K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as COSV101021882; called by muse, mutect2, varscan2
- MED12L | c.3215C>T p.T1072I | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV99854936; called by muse, mutect2, varscan2
- MED23 | c.3892C>A p.L1298I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100645429, COSV63437388; called by muse, mutect2, varscan2
- MELK | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs116620621; called by muse, mutect2, varscan2
- METTL22 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.235); catalogued as rs577807779, COSV99371610; called by muse, mutect2
- MFSD6L | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100266941; called by muse, mutect2, varscan2
- MGA | c.4732G>A p.V1578I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs570484800, COSV99581830; called by muse, mutect2, varscan2
- MIOS | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100402920, COSV60767646; called by muse, mutect2, varscan2
- MMADHC | c.868A>G p.M290V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100307354; called by muse, mutect2, varscan2
- MMP21 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs767525512, COSV100916700; called by muse, varscan2
- MMUT | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs766529896, COSV51272223; called by muse, mutect2, varscan2
- MRGPRX3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs143238196; called by muse, mutect2, varscan2
- MRPS11 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372417211; called by muse, mutect2
- MRRF | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV99939075; called by muse, mutect2, varscan2
- MSL2 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99388320; called by muse, mutect2, varscan2
- MST1R | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199869962, COSV56567197; called by muse, mutect2, varscan2
- MTHFR | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs749729349, COSV100412194; called by muse, mutect2, varscan2
- MTM1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs886044782, CP973606, COSV100080294; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- MTOR | c.5521A>G p.T1841A | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100816736; called by muse, mutect2, varscan2
- MUC16 | c.13394C>A p.P4465H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV101201916; called by muse, mutect2, varscan2
- MUC17 | c.247T>A p.L83M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as COSV100075296; called by muse, mutect2, varscan2
- MYBPC3 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as rs730880694, COSV99921036; called by muse, mutect2, varscan2
- MYCBP2 | c.2854C>T p.P952S (on ENST00000357337; = p.P990S on NM_015057.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100632123; called by muse, varscan2
- MYCL | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768216635, COSV65693368; called by muse, mutect2, varscan2
- MYH9 | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201967008, COSV99339936; called by muse, varscan2
- MYO10 | c.5944G>A p.V1982I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs186433188, COSV57031767; called by muse, mutect2, varscan2
- MYO1F | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769899272, COSV57799134; called by muse, mutect2, varscan2
- MYO9A | c.7007T>C p.L2336P | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100614456; called by muse, mutect2, varscan2
- MYOM2 | c.2203A>G p.K735E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.341); catalogued as rs757677237, COSV100038545; called by muse, mutect2, varscan2
- MYPN | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV100590693; called by muse, mutect2, varscan2
- MZF1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.43); catalogued as COSV99285485; called by muse, mutect2, varscan2
- NBPF20 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 27/177 reads (15%) | catalogued as rs1553665948; called by muse, mutect2, varscan2
- NCOR1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV52001387, COSV99252422; called by muse, mutect2, varscan2
- NDUFB6 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100598363; called by muse, mutect2, varscan2
- NDUFS4 | c.425-2A>G p.X142_splice | Splice Site (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99692492; called by muse, mutect2, varscan2
- NEB | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.995); catalogued as COSV99428524; called by muse, mutect2, varscan2
- NECAP2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1474257576, COSV61434475; called by muse, mutect2, varscan2
- NEIL1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1040169862, COSV99145899; called by muse, mutect2, varscan2
- NEK9 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99464582; called by muse, mutect2, varscan2
- NEO1 | c.2677G>A p.V893I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as rs774583216, COSV56078935, COSV99982900; called by muse, mutect2, varscan2
- NID1 | c.2623G>A p.V875I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.182); catalogued as rs201166678, COSV51628111; called by muse, mutect2, varscan2
- NIN | c.5222C>T p.A1741V (on ENST00000382041 / NM_182946.1; = p.A1028V on NM_016350.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs762668291, COSV55397086, COSV55397898; called by muse, mutect2, varscan2
- NIN | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs769277029, COSV55403382; called by muse, mutect2, varscan2
- NLE1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as rs753158734, COSV100681191; called by muse, mutect2, varscan2
- NMNAT1 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101020464; called by muse, mutect2, varscan2
- NMUR1 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1263647836, COSV59405402; called by muse, mutect2, varscan2
- NODAL | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as rs776830054, COSV99755647; called by muse, varscan2
- NOL4L | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100675720; called by muse, mutect2, varscan2
- NOM1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.195); catalogued as rs142522087; called by muse, mutect2, varscan2
- NOXO1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1358642313, COSV99937119; called by muse, mutect2, varscan2
- NPAT | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1565304932, COSV53716516; called by muse, mutect2, varscan2
- NR1D1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs953925397, COSV99225366, COSV99225840; called by muse, mutect2, varscan2
- NRAP | c.2036G>T p.S679I (on ENST00000359988 / NM_001322945.2; = p.S644I on NM_006175.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100748637; called by muse, mutect2
- NRDE2 | c.268del p.R90Gfs*69 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs1249617548, COSV62963847; called by mutect2, pindel, varscan2
- NSD1 | c.4873C>T p.P1625S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs1251053638, COSV100729872; called by muse, mutect2, varscan2
- NUP155 | c.2139A>C p.E713D (on ENST00000231498 / NM_153485.3; = p.E654D on NM_004298.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as COSV99195325; called by muse, mutect2, varscan2
- NUTM2G | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100672981; called by muse, mutect2, varscan2
- OBSCN | c.5690G>A p.R1897Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs758395622, COSV99484912; called by muse, varscan2
- OBSCN | c.23564T>C p.V7855A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100806030; called by muse, mutect2
- OLFM1 | c.1441C>T p.R481C (on ENST00000371793 / NM_001282611.2; = p.R463C on NM_014279.5) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1401300491, COSV53277207; called by muse, mutect2, varscan2
- OPCML | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100097591; called by muse, mutect2, varscan2
- OPN5 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV99790072; called by muse, mutect2, varscan2
- OR10X1 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100936718; called by muse, mutect2, varscan2
- OR1M1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs148262558; called by muse, mutect2, varscan2
- OR2M3 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101513532, COSV71758983; called by muse, mutect2, varscan2
- OR51F2 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100438179; called by muse, mutect2, varscan2
- OR52E8 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV101191120; called by muse, mutect2, varscan2
- OR7G3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as rs779363807, COSV59640532; called by muse, mutect2, varscan2
- OSBPL6 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs759571487, COSV51913807; called by muse, mutect2, varscan2
- OTOF | c.5180G>A p.R1727Q (on ENST00000272371 / NM_194248.3; = p.R960Q on NM_004802.4) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775472304, COSV99718899, COSV99719171; called by muse, varscan2
- PACS1 | c.2494G>A p.G832R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.537); catalogued as COSV100270062; called by muse, mutect2
- PADI2 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100971108; called by muse, mutect2, varscan2
- PAXBP1 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs1469650006, COSV99269564; called by muse, mutect2, varscan2
- PCBP2 | c.524dup p.K176Efs*46 | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | catalogued as rs776329515; called by mutect2, varscan2
- PCCB | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99291719; called by muse, mutect2, varscan2
- PCDHB11 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as COSV99505112; called by muse, mutect2, varscan2
- PCDHB3 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.263); catalogued as COSV99166859; called by muse, varscan2
- PCDHGA12 | c.2178G>T p.Q726H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV99342613; called by muse, mutect2
- PCDHGA7 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs1479729851, COSV99548098; called by muse, mutect2, varscan2
- PDAP1 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.981); catalogued as COSV99769255; called by muse, mutect2, varscan2
- PDCD1 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.196); catalogued as COSV100545586; called by muse, mutect2, varscan2
- PDE10A | c.1739A>G p.H580R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV100605936; called by muse, mutect2, varscan2
- PDE3B | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as COSV99963387; called by muse, mutect2, varscan2
- PER1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754833477, COSV100424890; called by muse, varscan2
- PER2 | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747864824, COSV99612658; called by muse, varscan2
- PFAS | c.1979G>T p.S660I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100119190, COSV58982137; called by muse, mutect2, varscan2
- PFKFB1 | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100895873; called by muse, mutect2, varscan2
- PGBD4 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.433); catalogued as COSV99855008; called by muse, mutect2, varscan2
- PHF12 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.885); catalogued as COSV99256295; called by muse, mutect2, varscan2
- PHF14 | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs760354638, COSV101301867; called by muse, mutect2
- PIGK | c.960A>T p.Q320H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100769963; called by muse, mutect2, varscan2
- PIGQ | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99216598; called by muse, mutect2, varscan2
- PIK3CB | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs763514461; called by muse, mutect2
- PKD1L1 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs758340178, COSV99221552; called by muse, mutect2, varscan2
- PLA2G2C | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs752921982, COSV99930400; called by muse, mutect2, varscan2
- PLA2G4E | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101268652; called by muse, mutect2, varscan2
- PLAT | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs773140572, COSV99535039; called by muse, mutect2, varscan2
- PLEC | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV100519660; called by muse, varscan2
- PLEKHA6 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1408129373, COSV99692868; called by muse, mutect2, varscan2
- PLEKHB2 | c.508G>A p.V170M (on ENST00000409279; = p.V169M on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs770198716, COSV99301848, COSV99301882; called by muse, mutect2, varscan2
- PLEKHN1 | c.967G>A p.V323I (on ENST00000379409; = p.V271I on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs376493040; called by muse, varscan2
- PLOD1 | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99539107; called by muse, mutect2, varscan2
- PLXNB3 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV100737997; called by muse, mutect2, varscan2
- PNISR | c.1915A>G p.R639G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as COSV100984439; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100544570; called by muse, mutect2, varscan2
- POLDIP2 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs782542378, COSV50228336; called by muse, mutect2, varscan2
- POM121 | c.2261C>T p.A754V (on ENST00000434423; = p.A489V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.395); catalogued as rs1456605273, COSV57513291; called by muse, mutect2, varscan2
- POMC | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360181016, COSV99257031; called by muse, mutect2, varscan2
- PPP1R26 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs776026138, COSV100778169; called by muse, varscan2
- PPP2R5B | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs747411292, CM159732, COSV99375930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP3CA | c.919del p.S307Qfs*6 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs1295066766; called by mutect2, pindel, varscan2
- PRAG1 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100422927; called by muse, mutect2, varscan2
- PRAMEF4 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV99340291; called by muse, mutect2, varscan2
- PRDM14 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52575826; called by muse, mutect2, varscan2
- PREX2 | c.3643C>T p.R1215W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs964579317, COSV55794645, COSV99906090; called by muse, mutect2, varscan2
- PRKCB | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100335524; called by muse, mutect2, varscan2
- PRL | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.501); catalogued as COSV100123248; called by muse, mutect2
- PRL | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.009); catalogued as rs1019269066, COSV100122987; called by muse, mutect2, varscan2
- PROM1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); catalogued as COSV101477143; called by muse, varscan2
- PRPF4 | c.571C>T p.R191C (on ENST00000374198 / NM_001322267.2; = p.R192C on NM_004697.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100950783; called by muse, mutect2, varscan2
- PRRC2B | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs756979652, COSV100261166; called by muse, varscan2
- PRXL2A | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100939839; called by muse, mutect2, varscan2
- PSAP | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV101206540; called by muse, mutect2, varscan2
- PSMB9 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs148645171, COSV66399825; called by muse, mutect2, varscan2
- PSMD2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV59531844; called by muse, mutect2, varscan2
- PTEN | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV100911451; called by muse, mutect2, varscan2
- PTH1R | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100481195; called by muse, mutect2
- PTPRM | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764281560, COSV100160230; called by muse, mutect2, varscan2
- PTPRU | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.163); catalogued as rs747115361, COSV100113853; called by muse, mutect2, varscan2
- PTPRZ1 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV66444250; called by muse, mutect2, varscan2
- PURA | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100495813; called by muse, mutect2, varscan2
- PYM1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs773714243, COSV100212604; called by muse, mutect2, varscan2
- PYROXD2 | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs141962703; called by muse, varscan2
- RAB11FIP5 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs1411409678, COSV50248520, COSV50250273; called by muse, mutect2, varscan2
- RAD23A | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs761578570, COSV100331145; called by muse, mutect2, varscan2
- RAP1GAP2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs770280991, COSV99624515; called by muse, mutect2, varscan2
- RAPGEF1 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100940858; called by muse, mutect2, varscan2
- RARA | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.812); catalogued as rs773619675, COSV99565507; called by muse, varscan2
- RASGRF2 | c.2291G>A p.S764N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.38); catalogued as COSV99430633; called by muse, mutect2, varscan2
- RBL1 | c.2063G>A p.S688N | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100727323; called by muse, mutect2, varscan2
- RBM25 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs1297968663, COSV99998978; called by muse, mutect2, varscan2
- RBMS1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs751679060, COSV100817129; called by muse, mutect2, varscan2
- RBMXL2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs749747785, COSV100182581; called by muse, varscan2
- RC3H1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1200190836, COSV51208585; called by muse, mutect2, varscan2
- RCE1 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 86/121 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as rs970514139, COSV100547194; called by muse, mutect2, varscan2
- RECQL4 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs767722327, COSV99468327; ClinVar: uncertain significance; called by muse, varscan2
- RFX6 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300421713, COSV100264366; called by muse, mutect2, varscan2
- RFX7 | c.631C>T p.Q211* (on ENST00000559447 / NM_001368074.1; = p.Q308* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100429499; called by muse, mutect2, varscan2
- RIC8A | c.1511G>A p.R504Q (on ENST00000526104 / NM_001286134.1; = p.R510Q on NM_021932.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs141562542; called by muse, mutect2, varscan2
- RNF112 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as rs944728278, COSV101465430; called by muse, mutect2, varscan2
- RNF113B | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99940438; called by muse, varscan2
- ROCK1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs374052961; called by muse, mutect2, varscan2
- ROS1 | c.2962G>A p.A988T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100877753; called by muse, mutect2, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs757272743; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS11 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.903); catalogued as rs746359465, COSV99569441; called by muse, mutect2, varscan2
- RPS6KB2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs146762475, COSV57048437; called by muse, varscan2
- RRP1B | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100513281; called by muse, mutect2, varscan2
- RS1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1402116265, CM136243, COSV66107582; called by muse, mutect2, varscan2
- RSPH10B2 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99786412; called by muse, mutect2, varscan2
- RSPRY1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.852); catalogued as rs200887019, COSV68028599; called by muse, mutect2, varscan2
- RTL5 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV65452846; called by muse, mutect2, varscan2
- RUBCN | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs376918359; called by muse, mutect2, varscan2
- RUNX2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs376891808; called by muse, mutect2, varscan2
- RYR2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.945); catalogued as rs1036926941, COSV63667488, COSV63684165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs1209694153, COSV100773169; called by muse, mutect2, varscan2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs749201569; called by mutect2, varscan2
- SAGE1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100188012; called by muse, mutect2, varscan2
- SALL4 | c.2983dup p.V995Gfs*16 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs753320334; called by mutect2, varscan2
- SALL4 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs751089738, COSV53854036; called by muse, mutect2, varscan2
- SAMD11 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs144010167; called by muse, mutect2, varscan2
- SCN10A | c.5333C>A p.P1778Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101479552; called by muse, mutect2, varscan2
- SCUBE1 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs138417338; called by muse, mutect2, varscan2
- SEC14L5 | c.1958T>C p.V653A | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV99229469; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SECISBP2 | c.457dup p.T153Nfs*3 | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | catalogued as rs1207508166; called by mutect2, varscan2
- SETDB1 | c.3821G>A p.G1274D (on ENST00000271640 / NM_001366417.1; = p.G1273D on NM_012432.4) | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99645959; called by muse, mutect2, varscan2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs759211171; called by mutect2, varscan2
- SFXN4 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs1254398721, COSV100341276; called by muse, mutect2, varscan2
- SGK2 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.511); catalogued as COSV100414865; called by muse, varscan2
- SH2D3A | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs765689594, COSV55586367, COSV55588318; called by muse, mutect2, varscan2
- SHC1 | c.1642C>T p.R548C (on ENST00000368445 / NM_183001.5; = p.R439C on NM_003029.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs201315943, COSV63534769; called by muse, mutect2, varscan2
- SIPA1L2 | c.3642C>T p.H1214= | Splice Region (SNP) | VAF 13/35 reads (37%) | catalogued as rs367736584; called by muse, mutect2, varscan2
- SIRPA | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.434); catalogued as rs1246015069, COSV61538145; called by muse, mutect2, varscan2
- SLA2 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99481610; called by muse, mutect2, varscan2
- SLC12A6 | c.2824C>T p.R942W (on ENST00000354181 / NM_001365088.1; = p.R891W on NM_005135.2) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433837086, COSV99273533; called by muse, mutect2, varscan2
- SLC17A9 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100948014; called by muse, mutect2, varscan2
- SLC18A2 | c.1307-2A>G p.X436_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100042161; called by muse, mutect2, varscan2
- SLC1A1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780117919, COSV99261631; called by muse, mutect2, varscan2
- SLC22A25 | c.1395G>T p.R465S | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100124053, COSV60594910; called by muse, mutect2, varscan2
- SLC23A2 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); catalogued as rs759317661, COSV100595350; called by muse, mutect2, varscan2
- SLC25A45 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248005144, COSV99587443; called by muse, mutect2, varscan2
- SLC25A47 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs767646444, COSV100690390; called by muse, varscan2
- SLC26A9 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.699); catalogued as rs574530028, COSV61601093; called by muse, mutect2, varscan2
- SLC35E3 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99972114; called by muse, mutect2, varscan2
- SLC35G5 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs532136763, COSV55312683; called by mutect2, varscan2
- SLC36A4 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1162550205, COSV100419490; called by muse, mutect2, varscan2
- SLC38A10 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.101); catalogued as rs755525430, COSV99917988; called by muse, varscan2
- SLC38A6 | c.625-1G>T p.X209_splice | Splice Site (SNP) | VAF 26/67 reads (39%) | catalogued as COSV50786513; called by muse, mutect2, varscan2
- SLC38A8 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs148856738; called by muse, mutect2, varscan2
- SLC45A4 | c.1990T>C p.C664R (on ENST00000517878 / NM_001286646.2; = p.C613R on NM_001080431.2) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99200699; called by muse, mutect2, varscan2
- SLC5A4 | c.754A>G p.S252G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99832183; called by muse, mutect2, varscan2
- SLC6A20 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149068093; called by muse, varscan2
- SLC6A3 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs746715018, COSV99548940; called by muse, mutect2
- SLFNL1 | c.1153A>G p.M385V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100263192; called by muse, mutect2, varscan2
- SLITRK5 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100281278, COSV61524178; called by muse, mutect2, varscan2
- SMAP1 | c.731A>G p.D244G (on ENST00000370455 / NM_001044305.3; = p.D217G on NM_021940.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100017489; called by muse, mutect2, varscan2
- SMARCC2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57217936; called by muse, mutect2, varscan2
- SMG6 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs746297201, COSV99558859; called by muse, mutect2, varscan2
- SMIM29 | c.61G>A p.V21I (on ENST00000394990 / NM_001008704.3; = p.V41I on NM_178508.5) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142296874; called by muse, mutect2, varscan2
- SNUPN | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs377184433; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs746109620; called by mutect2, varscan2
- SPAG11A | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1167818335, COSV100429484; called by muse, mutect2, varscan2
- SPC24 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs367711378, COSV70607198; called by muse, varscan2
- SPTBN1 | c.1259T>A p.L420Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100443523; called by muse, mutect2, varscan2
- SRCAP | c.6536del p.K2179Rfs*128 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as COSV52675361; called by mutect2, pindel, varscan2
- SRCIN1 | c.3089G>A p.R1030H (on ENST00000621492; = p.R996H on NM_025248.3) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs762091160; called by muse, mutect2, varscan2
- SRGAP3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs149157821; called by muse, mutect2, varscan2
- ST3GAL5 | c.1021G>T p.A341S (on ENST00000377332; = p.A381S on NM_003896.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.042); catalogued as COSV101062274; called by muse, mutect2, varscan2
- ST6GAL2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | PolyPhen benign (0.177); catalogued as rs920131957, COSV100868308; called by muse, mutect2, varscan2
- STARD5 | c.282C>T p.D94= | Splice Region (SNP) | VAF 15/35 reads (43%) | catalogued as rs745566069, COSV100250793; called by muse, mutect2, varscan2
- STK10 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.025); catalogued as rs369344814; called by muse, varscan2
- STK26 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100688910; called by muse, mutect2, varscan2
- SUDS3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV64348866; called by muse, mutect2, varscan2
- SUFU | c.430T>G p.L144V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100883208; called by muse, mutect2, varscan2
- SUMF1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs781069134, COSV99795184; called by muse, mutect2, varscan2
- SUPT16H | c.1178del p.K393Sfs*29 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as COSV53526696; called by mutect2, pindel, varscan2
- SUPV3L1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs748585973, COSV62845525; called by muse, mutect2, varscan2
- SUV39H1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100551672, COSV61921377; called by muse, mutect2
- SUV39H1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100551879; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs753462162; called by mutect2, varscan2
- SYTL2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as rs778754109, COSV100315047; called by muse, mutect2, varscan2
- TAF1 | c.4409G>A p.R1470H (on ENST00000373790 / NM_138923.4; = p.R1491H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52130359; called by muse, mutect2, varscan2
- TANGO2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs377447080; called by muse, varscan2
- TAOK2 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99665599; called by muse, mutect2, varscan2
- TARS2 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749517234, COSV60875424; called by muse, mutect2, varscan2
- TATDN2 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as rs778424624, COSV99813775; called by muse, mutect2, varscan2
- TBC1D10A | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.545); catalogued as rs752820539, COSV53162790; called by muse, mutect2, varscan2
- TBC1D17 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99680970; called by muse, mutect2, varscan2
- TBC1D8 | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs752493871, COSV100964665; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF7L2 | c.917C>T p.T306M (on ENST00000355995 / NM_001367943.1; = p.T283M on NM_030756.5) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs951950988, COSV53337723; called by muse, mutect2, varscan2
- TCOF1 | c.2389G>A p.A797T (on ENST00000377797 / NM_001135243.1; = p.A720T on NM_000356.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757336927, COSV100078451; called by muse, varscan2
- TECPR1 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554435624, COSV101130793; called by muse, varscan2
- TENM1 | c.4468A>G p.K1490E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV100951139; called by muse, mutect2
- TENM2 | c.2453G>T p.G818V (on ENST00000518659 / NM_001122679.2; = p.G586V on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101319476; called by muse, mutect2
- TET2 | c.791T>A p.I264N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99485067; called by muse, mutect2, varscan2
- TEX13A | c.574G>T p.G192* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs782062617, COSV61150419; called by muse, mutect2, varscan2
- TEX9 | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV100771719; called by muse, mutect2, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs544132101; called by mutect2, varscan2
- TGM6 | c.1931A>G p.E644G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99172931; called by muse, mutect2, varscan2
- TLK2 | c.1531G>A p.A511T (on ENST00000326270 / NM_001284333.2; = p.A489T on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100409620; called by muse, mutect2, varscan2
- TLR10 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100458108; called by muse, mutect2, varscan2
- TMC5 | c.1844G>A p.R615H (on ENST00000396229 / NM_001105248.1; = p.R369H on NM_024780.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs369956293; called by muse, mutect2, varscan2
- TMCC1 | c.1843A>G p.M615V (on ENST00000393238 / NM_001349268.2; = p.M291V on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs1005600501, COSV100261354; called by muse, mutect2, varscan2
- TMCC2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as rs1033504397, COSV100405711, COSV100405812; called by muse, mutect2
- TMEM101 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs756067708, COSV99244001; called by muse, varscan2
- TMEM104 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753954018, COSV59107697; called by muse, mutect2, varscan2
- TMEM168 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760899014, COSV57179224; called by muse, mutect2, varscan2
- TMEM208 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99264566; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs748106478, COSV100925350; called by muse, mutect2, varscan2
- TNKS | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100127964; called by muse, varscan2
- TNR | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.352); catalogued as rs779084932, COSV99689051, COSV99690406; called by muse, mutect2, varscan2
- TOM1L2 | c.934C>T p.R312* (on ENST00000379504 / NM_001350333.2; = p.R262* on NM_001033551.3) | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs769833356, COSV100541263; called by muse, mutect2, varscan2
- TPM2 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100253563; called by muse, mutect2, varscan2
- TRIM32 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs564290779, COSV100530717; called by muse, mutect2, varscan2
- TRIM37 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs757431303, COSV99233525; called by muse, mutect2, varscan2
- TRIM44 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs760616658, COSV54984427; called by muse, mutect2, varscan2
- TRIM71 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1269913539, COSV101070519; called by muse, mutect2, varscan2
- TRIOBP | c.4030C>T p.R1344* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs1310590474, COSV100731165; called by muse, mutect2, varscan2
- TRO | c.310T>C p.W104R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99437414; called by muse, mutect2, varscan2
- TRPC6 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.965); catalogued as rs750792087, COSV60258215, COSV60261012; called by muse, mutect2, varscan2
- TRPM4 | c.2952C>T p.D984= | Splice Region (SNP) | VAF 10/49 reads (20%) | catalogued as COSV53264469, COSV53265019; called by muse, mutect2, varscan2
- TSC22D3 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV100227029; called by muse, mutect2, varscan2
- TSHZ3 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV99552935; called by muse, mutect2, varscan2
- TSPAN33 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs768190545, COSV56825609; called by muse, mutect2, varscan2
- TSPAN7 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV99731416; called by muse, mutect2, varscan2
- TSSK1B | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs374009361; called by muse, mutect2, varscan2
- TSSK3 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.054); catalogued as rs774698904, COSV100345166; called by muse, varscan2
- TTC13 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376123252; called by muse, mutect2, varscan2
- TTC27 | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1197648924, COSV100513666; called by muse, mutect2, varscan2
- TTN | c.98806C>G p.Q32936E (on ENST00000591111; = p.Q25512E on NM_003319.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | PolyPhen possibly damaging (0.717); catalogued as COSV59893179, COSV60293395; called by muse, mutect2, varscan2
- TTN | c.33406C>T p.P11136S (on ENST00000591111; = p.P10209S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | PolyPhen benign (0.359); catalogued as rs375905219; called by muse, mutect2, varscan2
- TTYH2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs139572666; called by muse, varscan2
- TUT4 | c.3521G>A p.R1174H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.114); catalogued as rs549447166, COSV57111951, COSV57117437; called by muse, mutect2, varscan2
- UBQLN4 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs757542069, COSV64145280; called by muse, mutect2, varscan2
- UGT8 | c.1582T>C p.Y528H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774647733, COSV100179403; called by muse, mutect2, varscan2
- UNKL | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs764487487, COSV99201679; called by muse, varscan2
- USF3 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.691); catalogued as COSV100325857; called by muse, mutect2, varscan2
- USP54 | c.1642C>A p.L548M | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV60444638; called by muse, mutect2, varscan2
- UTRN | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196247080, COSV62327898; called by muse, mutect2, varscan2
- VASP | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs759805062, COSV99841179; called by muse, mutect2, varscan2
- VCAN | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99427513; called by muse, mutect2, varscan2
- VNN2 | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as rs1174578550, COSV100426968; called by muse, mutect2
- VWA3B | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs766367859, COSV101346179, COSV68244310; called by muse, mutect2, varscan2
- WDCP | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs772341651, COSV99722253; called by muse, mutect2, varscan2
- WDR24 | c.878C>T p.S293L (on ENST00000248142; = p.S163L on NM_032259.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs762076686, COSV99556047; called by muse, varscan2
- WDR27 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772785976, COSV100359893; called by muse, varscan2
- WDR45 | c.461T>C p.L154P (on ENST00000376372 / NM_001029896.2; = p.L155P on NM_007075.3) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100540398; called by muse, mutect2, varscan2
- WDR45B | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs1391857942, COSV101124474; called by muse, mutect2, varscan2
- WDR70 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); catalogued as COSV99460642, COSV99461100; called by muse, mutect2, varscan2
- WDR82 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV99627270; called by muse, mutect2
- WNK3 | c.3737C>T p.T1246I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100672230; called by muse, mutect2, varscan2
- WNT5A | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99225077; called by muse, mutect2, varscan2
- WWOX | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370737224, COSV68347719; called by muse, mutect2, varscan2
- XIRP2 | c.4807A>G p.K1603E (on ENST00000628543; = p.K1778E on NM_152381.6) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99748134; called by muse, mutect2, varscan2
- XPNPEP1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777538747, COSV59171185; called by muse, mutect2, varscan2
- YEATS2 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs376025260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YTHDC1 | c.1607G>A p.R536Q (on ENST00000344157 / NM_001031732.4; = p.R518Q on NM_133370.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs563538919, COSV100704887; called by muse, mutect2, varscan2
- ZBED2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs200363231, COSV99343663; called by muse, varscan2
- ZBTB14 | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100813514; called by muse, mutect2, varscan2
- ZC3H12B | c.1504del p.H502Tfs*48 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as COSV59051458; called by mutect2, pindel, varscan2
- ZC3H13 | c.2389C>T p.R797* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | catalogued as COSV54463725; called by muse, mutect2, varscan2
- ZC3H13 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs776281684, COSV54448054; called by muse, mutect2, varscan2
- ZDHHC23 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100362270, COSV57628824; called by muse, mutect2, varscan2
- ZDHHC9 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100852306; called by muse, mutect2, varscan2
- ZFC3H1 | c.4037A>G p.D1346G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1405742521, COSV101110711; called by muse, mutect2, varscan2
- ZFYVE9 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs925702512, COSV99820788; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100363067; called by muse, mutect2, varscan2
- ZNF2 | c.628G>T p.G210W (on ENST00000611147 / NM_001291605.2; = p.G197W on NM_021088.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728726; called by muse, mutect2, varscan2
- ZNF214 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs761761738, COSV99547689; called by muse, mutect2, varscan2
- ZNF280C | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs200242962, COSV63968955; called by muse, mutect2, varscan2
- ZNF496 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs750169761, COSV54179067; called by muse, mutect2, varscan2
- ZNF506 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs778208194, COSV101475652, COSV71354276; called by muse, mutect2, varscan2
- ZNF573 | c.1427G>T p.G476V (on ENST00000536220 / NM_001172692.1; = p.G418V on NM_152360.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265876; called by muse, mutect2, varscan2
- ZNF629 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52697379; called by muse, mutect2
- ZNF721 | c.1000G>A p.A334T (on ENST00000338977; = p.A346T on NM_133474.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as rs782527529, COSV100167919; called by muse, mutect2, varscan2
- ZNF780B | c.1291A>C p.N431H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs1401337689, COSV99666209; called by muse, mutect2
- ZP1 | c.1894C>T p.L632F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV99612880; called by muse, mutect2, varscan2
- ZSCAN2 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as rs777228309, COSV100491566; called by muse, varscan2
- ZSCAN20 | c.163A>T p.R55W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.866); catalogued as COSV100792756; called by muse, mutect2, varscan2
- ZWINT | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100571580; called by muse, mutect2, varscan2
- ZZEF1 | c.2890T>C p.F964L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.316); catalogued as COSV101068153; called by muse, mutect2, varscan2
- AMIGO1 | c.1205del p.G402Vfs*2 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- ATAD5 | c.218del p.N73Mfs*6 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by pindel, varscan2
- C12orf4 | c.40_41dup p.F15Nfs*8 | Frame Shift Ins (INS) | VAF 26/55 reads (47%) | called by mutect2, varscan2
- CCDC184 | c.511del p.D171Tfs*76 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, varscan2
- COQ9 | c.240del p.R81Gfs*24 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- CXCL9 | c.323del p.K108Rfs*4 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- DDOST | c.299del p.F100Sfs*5 (on ENST00000415136; = p.F83Sfs*5 on NM_005216.5) | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- DNAJC19 | c.348del p.K116Nfs*6 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- EAPP | c.374del p.K125Rfs*55 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, varscan2
- ENKUR | c.67del p.Q23Sfs*13 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- EP300 | c.4408del p.M1470Cfs*26 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- FAM76B | c.938del p.N313Tfs*24 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- FOXD4L1 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- GPR179 | c.3801dup p.W1268Lfs*5 (on ENST00000621958; = p.W1267Lfs*5 on NM_001004334.4) | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- GSTT2B | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- HNF1B | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- KRTAP2-4 | c.50del p.G17Efs*18 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel
- LAYN | c.604del p.E202Kfs*4 (on ENST00000375615 / NM_001258390.1; = p.E194Kfs*4 on NM_178834.5) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MAP2 | c.4420del p.T1474Qfs*14 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- MAP7D1 | c.2154_2163del p.R718Sfs*26 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- MEIS1 | c.304del p.R102Afs*20 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, varscan2
- MINPP1 | c.725del p.N242Mfs*21 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- NHLRC3 | c.411del p.K137Nfs*22 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- NINL | c.3381_3382del p.D1127Efs*7 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- OR4K17 | c.900dup p.L301Tfs*9 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- PAK6 | c.1938_1939del p.R646Sfs*19 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by pindel, varscan2
- PNRC2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | called by mutect2, pindel, varscan2
- PRDM1 | c.1251del p.Y418Tfs*3 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- PTCHD3 | c.1084del p.I362Lfs*3 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, varscan2
- ROBO2 | c.507dup p.D170Rfs*6 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- SIN3A | c.450_452del p.I150del | In Frame Del (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2
- SRSF10 | c.171-2A>G p.X57_splice | Splice Site (SNP) | VAF 71/275 reads (26%) | called by muse, mutect2, varscan2
- TCF7L1 | c.966del p.S323Afs*2 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, varscan2
- THYN1 | c.581del p.N194Ifs*15 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- TPR | c.495del p.K165Nfs*33 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- ZNF518A | c.4295del p.N1432Tfs*6 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- ABCA3 | c.907C>T p.L303= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as CM120587, COSV100069176; called by muse, mutect2, varscan2
- ABCE1 | c.1593C>T p.R531= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1363635437, COSV99668866; called by muse, mutect2, varscan2
- ABR | c.1995G>A p.R665= (on ENST00000302538 / NM_021962.5; = p.R628= on NM_001092.5) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs975440246, COSV99348717; called by muse, mutect2, varscan2
- ACP6 | c.1155G>A p.P385= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs782111895, COSV100984263; called by muse, mutect2, varscan2
- ACTG2 | c.441C>T p.G147= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100609552; called by muse, mutect2, varscan2
- ACTL9 | c.564C>T p.H188= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV61005582; called by muse, mutect2, varscan2
- ADAM7 | c.585C>A p.I195= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99442836, COSV99443656; called by muse, mutect2, varscan2
- AEBP1 | c.2463C>T p.S821= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1367575857, COSV56255518, COSV99789154; called by muse, mutect2, varscan2
- ALDH3B2 | c.579C>T p.D193= | Silent (SNP) | VAF 36/213 reads (17%) | catalogued as rs747155176, COSV100824150; called by muse, mutect2, varscan2
- ALOX15B | c.1245C>T p.L415= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1233790468, COSV66479093; called by muse, varscan2
- AMHR2 | c.1269C>T p.R423= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99143649; called by muse, mutect2, varscan2
- AP002748.5 | c.1506C>T p.R502= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs756550025, COSV59149565; ClinVar: likely benign; called by muse, mutect2, varscan2
- AP5S1 | c.462G>A p.A154= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs138405532; called by muse, mutect2, varscan2
- ARHGAP20 | c.2838C>T p.S946= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs760491979, COSV52816708, COSV52821085; called by muse, mutect2, varscan2
- ARHGAP35 | c.993G>A p.E331= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101351807; called by muse, mutect2, varscan2
- ARMC3 | c.2460C>T p.Y820= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs762403977, COSV53070431; called by muse, mutect2, varscan2
- ARRDC5 | c.696C>T p.Y232= (on ENST00000381781; = p.Y218= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs549100453, COSV67788152; called by muse, mutect2, varscan2
- ARSL | c.753C>T p.A251= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs756226879, COSV101140798; called by muse, mutect2, varscan2
- ASB12 | c.498C>T p.N166= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs147025022, COSV100744841; called by muse, mutect2, varscan2
- ASCC3 | c.3375C>T p.S1125= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs762570153, COSV100226408; called by muse, mutect2, varscan2
- ASIC5 | c.834C>T p.H278= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs771533226, COSV101611188; called by muse, mutect2, varscan2
- ASXL2 | c.2148C>T p.G716= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99712127; called by muse, mutect2, varscan2
- ATAD2 | c.1197C>T p.G399= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs572210705, COSV54887242; called by muse, mutect2
- ATF2 | c.1047A>G p.E349= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99909061; called by muse, mutect2, varscan2
- ATF6B | c.1995G>A p.S665= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs776834249, COSV64351570; called by muse, mutect2
287 further variants in this file (0 protein-altering or splice-affecting, 256 silent, 31 other) are not listed here.
